Somatic mutation profile of tumor specimen TCGA-F5-6863-01A (aliquot TCGA-F5-6863-01A-11D-1924-10) from TCGA case TCGA-F5-6863, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 71.0 years (25,936 days).
Specimen TCGA-F5-6863-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8736092-23ec-4501-b662-bab91595e97c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6863-10A (Blood Derived Normal), aliquot TCGA-F5-6863-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7ea3fb2-3b79-48f5-a7a2-b865d7d2866a

The open-access MAF lists 71 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 13, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 1, Intron 1, In Frame Ins 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1312+1G>A p.X438_splice | Splice Site (SNP) | VAF 36/132 reads (27%) | catalogued as rs863225310, CS021159, CS130068, COSV57326024, COSV57343038, COSV57388892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3815C>G p.S1272* | Nonsense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as rs863225348, CD106449, CM040676, COSV57348860, COSV57351844, COSV57380973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 68/90 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 27/44 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC092143.1 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs529172770, COSV59248048; called by muse, mutect2, varscan2
- C1R | c.76T>C p.F26L (on ENST00000536053 / NM_001354346.2; = p.F12L on NM_001733.7) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV56925564; called by muse, mutect2, varscan2
- C4orf50 | c.427G>A p.V143I (on ENST00000324058; = p.V1375I on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs750915133, COSV100135761, COSV60688547; called by muse, mutect2, varscan2
- CACNA1H | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756266849, COSV61993629; called by muse, mutect2, varscan2
- CADPS | c.3901C>T p.R1301* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs141301525, COSV51881188; called by muse, mutect2, varscan2
- CASZ1 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as COSV59737010; called by muse, mutect2, varscan2
- CLEC1A | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100191433; called by mutect2, varscan2
- COL14A1 | c.2964T>A p.Y988* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as COSV99919202; called by muse, mutect2, varscan2
- CSMD1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs781692154, COSV68262082; called by muse, mutect2, varscan2
- CSNK1A1L | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as rs1317209838, COSV65789807; called by muse, mutect2, varscan2
- CTNND1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs776232220, COSV62384141; called by muse, mutect2, varscan2
- DAB2 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57915550; called by muse, mutect2, varscan2
- DDX19B | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99849963; called by muse, varscan2
- DMD | c.7946G>A p.R2649Q | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as COSV58919615; called by muse, mutect2, varscan2
- DVL3 | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100493643; called by muse, mutect2, varscan2
- EMC1 | c.2239_2240del p.S747Hfs*6 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs773033814; called by pindel, varscan2
- FLG | c.9877C>G p.Q3293E | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.867); catalogued as COSV64243148; called by muse, mutect2, varscan2
- FLRT2 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV58143981, COSV58144150; called by muse, mutect2, varscan2
- HHATL | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.881); catalogued as COSV60042118; called by muse, mutect2
- HOGA1 | c.137T>C p.F46S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100080838; called by muse, varscan2
- KIF26B | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as rs200347978, COSV63643833; called by muse, mutect2, varscan2
- LRRN3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57820882; called by muse, mutect2, varscan2
- LRRTM1 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV54439358; called by muse, varscan2
- MITF | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.213); catalogued as rs781567478, COSV58884038; called by muse, varscan2
- NAA15 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 106/281 reads (38%) | catalogued as COSV56720419; called by muse, mutect2, varscan2
- NFATC2 | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65357345; called by muse, mutect2, varscan2
- NFKBIL1 | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.197); catalogued as COSV65990497; called by muse, mutect2
- NLRP7 | c.1584G>T p.E528D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV60171663; called by muse, mutect2, varscan2
- NPAP1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.413); catalogued as COSV61506613, COSV61508127; called by muse, mutect2, varscan2
- NTM | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs767842712, COSV66182770; called by muse, mutect2, varscan2
- OR52R1 | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as COSV61888695; called by muse, mutect2, varscan2
- OR6K6 | c.614T>C p.I205T (on ENST00000368144; = p.I181T on NM_001005184.1) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63744347; called by muse, mutect2, varscan2
- PARP8 | c.2405A>C p.H802P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV55861521; called by muse, mutect2, varscan2
- PCDHGA11 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53925839; called by muse, mutect2, varscan2
- PIGO | c.2635G>A p.V879I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs139155910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R13B | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs530083884, COSV52452825; called by muse, mutect2, varscan2
- PTPRC | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 188/351 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs776036789, COSV61413887; called by muse, mutect2, varscan2
- QRFP | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762548618, COSV58064972; called by muse, mutect2, varscan2
- RASSF1 | c.772+2T>G p.X258_splice (on ENST00000357043 / NM_170714.2; = p.X254_splice on NM_007182.5) | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99222727; called by muse, mutect2, varscan2
- RSBN1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99793247; called by muse, mutect2
- SACS | c.10498C>T p.L3500F | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs754075561, COSV66541705; called by muse, mutect2, varscan2
- SLIT2 | c.2380A>T p.N794Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56576780; called by muse, mutect2, varscan2
- SMYD3 | c.515T>C p.F172S (on ENST00000490107 / NM_001375962.1; = p.F113S on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs1266870508, COSV101194010; called by muse, varscan2
- STPG2 | c.866C>A p.S289Y | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99759253; called by muse, mutect2, varscan2
- TENM2 | c.794C>T p.S265L (on ENST00000518659 / NM_001122679.2; = p.S74L on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.096); catalogued as COSV69133269; called by muse, mutect2, varscan2
- TMEM177 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV55608959; called by muse, mutect2, varscan2
- TTN | c.73355G>A p.G24452E (on ENST00000591111; = p.G17028E on NM_003319.4) | Missense Mutation (SNP) | VAF 31/109 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV60131819; called by muse, mutect2, varscan2
- YTHDF2 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 129/176 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as rs1006472903, COSV65723188; called by muse, mutect2, varscan2
- ZNF536 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as rs777103163, COSV62826256; called by muse, mutect2, varscan2
- ZNF653 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53402067, COSV53402148; called by muse, mutect2, varscan2
- CAST | c.1863_1865dup p.L622dup (on ENST00000341926; = p.L705dup on NM_001750.7 and 2 other RefSeq transcripts) | In Frame Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- MRM1 | c.583dup p.A195Gfs*11 | Frame Shift Ins (INS) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- ANKS1A | c.2919G>A p.E973= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV64461597; called by muse, mutect2, varscan2
- DMP1 | c.1533C>T p.D511= | Silent (SNP) | VAF 48/76 reads (63%) | catalogued as rs534492304, COSV99218711; called by muse, mutect2, varscan2
- EPHB6 | c.738G>A p.T246= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs756943658, COSV101235986, COSV67421606; called by muse, mutect2, varscan2
- IFI27L1 | c.174C>T p.N58= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs752718253, COSV67628578; called by muse, mutect2, varscan2
- IRS2 | c.3819G>A p.P1273= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV65479265; called by muse, varscan2
- IRS4 | c.1668C>T p.H556= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV64532615; called by muse, mutect2, varscan2
- NID1 | c.834C>T p.D278= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs371831151; called by muse, mutect2, varscan2
- ODF2 | c.369T>C p.Y123= (on ENST00000434106 / NM_153433.2; = p.Y99= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1486076017, COSV63547578; called by muse, mutect2, varscan2
- OR5B12 | c.321T>C p.T107= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV56905374; called by muse, mutect2, varscan2
- PPEF2 | c.333C>T p.P111= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as rs199870938, COSV99714529; called by muse, varscan2
- STARD10 | c.834C>T p.G278= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs770104161, COSV58325824; called by muse, mutect2, varscan2
- TTN | c.3279G>A p.L1093= (on ENST00000591111; = p.L1047= on NM_003319.4) | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV60132069; called by muse, mutect2, varscan2
- ZNF804B | c.1881T>C p.F627= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV60832668; called by muse, mutect2, varscan2
- CDH5 | c.*2C>T | 3'UTR (SNP) | VAF 20/30 reads (67%) | catalogued as rs1267148293, COSV58516865; called by muse, mutect2, varscan2
- TTN | c.10360+4114G>T | Intron (SNP) | VAF 33/102 reads (32%) | catalogued as COSV59933745, COSV60132056; called by muse, mutect2, varscan2
